Somatic mutation profile of tumor specimen ALCH-ABV1-TTP1-A (aliquot ALCH-ABV1-TTP1-A-3-0-D-A489-36) from ALCHEMIST case ALCH-ABV1, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 56.4 years (20,589 days).
Specimen ALCH-ABV1-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b4416854-ac15-45a7-9a8a-3eec456f3d4f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-ABV1-NB1-A (Blood Derived Normal), aliquot ALCH-ABV1-NB1-A-1-0-D-A489-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f29b0515-9b9f-4d60-aa73-16f6fde5d15d

The open-access MAF lists 35 somatic variants for this specimen: 22 protein-altering or splice-affecting, 7 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 20, Silent 7, Nonsense Mutation 2, Intron 2, 3'Flank 1, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BAG6 | c.1069C>A p.H357N | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99277721; called by muse, mutect2
- DEPDC5 | c.932A>G p.N311S | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56708548; called by muse, mutect2
- DNAH11 | c.3161T>C p.L1054S | Missense Mutation (SNP) | VAF 14/213 reads (7%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.691); catalogued as rs1489671899; called by muse, mutect2
- PIH1D1 | c.241G>A p.V81M | Missense Mutation (SNP) | VAF 50/365 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs371259664; called by muse, mutect2, varscan2
- SEC14L5 | c.313C>T p.R105C | Missense Mutation (SNP) | VAF 89/737 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1048164104; called by muse, mutect2, varscan2
- BEND2 | c.1079A>G p.N360S | Missense Mutation (SNP) | VAF 37/240 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- DCST2 | c.1985G>T p.G662V | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.163); called by muse, mutect2
- IVD | c.736C>T p.L246F | Missense Mutation (SNP) | VAF 13/169 reads (8%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2
- KCNB1 | c.100C>T p.R34C | Missense Mutation (SNP) | VAF 20/194 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.149); called by muse, mutect2
- MACF1 | c.15874C>T p.Q5292* (on ENST00000372915; = p.Q3225* on NM_012090.5) | Nonsense Mutation (SNP) | VAF 18/168 reads (11%) | called by muse, mutect2
- MAP3K6 | c.3578G>A p.R1193Q | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, varscan2
- MED1 | c.763G>C p.A255P | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- MUC7 | c.767A>G p.E256G | Missense Mutation (SNP) | VAF 46/673 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.037); called by muse, mutect2
- NAGK | c.526G>C p.A176P | Missense Mutation (SNP) | VAF 28/443 reads (6%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by muse, mutect2
- NOVA2 | c.734C>A p.S245* | Nonsense Mutation (SNP) | VAF 4/28 reads (14%) | called by mutect2, varscan2
- OR6A2 | c.754G>C p.V252L | Missense Mutation (SNP) | VAF 20/494 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OSCAR | c.481A>G p.M161V | Missense Mutation (SNP) | VAF 58/419 reads (14%) | SIFT tolerated (0.76); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- RPTN | c.748T>C p.S250P | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2
- TENM1 | c.5158G>T p.V1720L | Missense Mutation (SNP) | VAF 16/190 reads (8%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, mutect2
- TRAK2 | c.1289C>G p.S430C | Missense Mutation (SNP) | VAF 21/578 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TRIM36 | c.1931T>G p.F644C | Missense Mutation (SNP) | VAF 30/291 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- UCHL5 | c.742A>G p.M248V | Missense Mutation (SNP) | VAF 27/217 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- ARID1B | c.5343G>A p.K1781= | Silent (SNP) | VAF 10/152 reads (7%) | called by muse, mutect2
- DDX24 | c.1611C>T p.L537= | Silent (SNP) | VAF 35/524 reads (7%) | catalogued as COSV58213783; called by muse, mutect2
- FAM160A1 | c.465C>T p.T155= | Silent (SNP) | VAF 29/232 reads (13%) | catalogued as rs1393059409; called by muse, mutect2, varscan2
- HEATR1 | c.4818G>C p.G1606= | Silent (SNP) | VAF 22/228 reads (10%) | called by muse, mutect2
- LRP2 | c.8946C>T p.Y2982= | Silent (SNP) | VAF 40/439 reads (9%) | catalogued as rs781541482, COSV55547693; called by muse, mutect2
- SLCO1B1 | c.552G>A p.G184= | Silent (SNP) | VAF 33/374 reads (9%) | called by muse, mutect2
- VTCN1 | c.138G>A p.G46= | Silent (SNP) | VAF 45/370 reads (12%) | called by muse, mutect2, varscan2
- CD99 | c.475+931G>A | Intron (SNP) | VAF 28/450 reads (6%) | called by muse, mutect2
- CRPPA | c.*2269A>T | 3'UTR (SNP) | VAF 24/190 reads (13%) | called by muse, varscan2
- MCCC1 | c.-12G>T | 5'UTR (SNP) | VAF 98/506 reads (19%) | called by muse, mutect2, varscan2
- MIR29B2 | chr1:207802425 del GCTGTGCTGC | 3'Flank (DEL) | VAF 10/78 reads (13%) | called by mutect2, pindel
- NPEPPS | c.2559+137A>C | Intron (SNP) | VAF 4/32 reads (13%) | called by muse, varscan2
- SYBU | chr8:109645251 A>G | 5'Flank (SNP) | VAF 267/1245 reads (21%) | catalogued as rs889686157; called by muse, mutect2, varscan2
